Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6220, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6220-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Nck: left facial nodes
2. Neck LT level 2B
3. Neck LT LEVEL 2
4. Neck LT LEVEL 3
5. Neck LT LEVEL 4
6. Neck LT LEVEL 1
7. Oral Cavity LT BUCCAL MASS STITCH ANTERIOR
8. Oral Cavity POSTERIOR MARGIN
9. Oral Cavity SUPERIOR MARGIN
10. Oral Cavity DEEP FAT PAD
11. Oral Cavity ANTERIOR MARGIN
12. Oral Cavity INTERIOR AVEOLAR MARGIN
13. Oral Cavity DEEP MARGIN

Diagnosis

1. Left facial lymph nodes.
Five lymph nodes negative for tumor (0/5).
2. Left level IIB.
Three lymph nodes negative for tumor (0/3).
3. Left level II.
Fourteen lymph nodes negative for tumor (0/14).
4. Left level III.
Seven lymph nodes negative for tumor (0/7).
5. Left level IV.
Nine lymph nodes negative for tumor (0/9).
6. Left level I.
Four lymph nodes negative for tumor (0/4).
Submandibular gland with no pathologic changes.

[page 2 of 4]
7. Oral Cavity; "left buccal mass, anterior".
Squamous cell carcinoma, moderately differentiated.
a. Tumor maximum diameter 5.0 cm.
b. Tumor thickness 1.5 cm.
c. No lymphatic/vascular invasion.
d. Perineural invasion is present.
e. Multiple margins (deep, inferior, superior, lateral) are close (0.2 cm) to tumor.

8. Posterior margin.
Negative for tumor.

9. Superior margin.
Negative for tumor.

10. Deep fat pad.
Negative for tumor.

11. Anterior margin.
Negative for tumor.

12. Interior alveolar margin.
Negative for tumor.

13. Deep margin.
Negative for tumor.

Synoptic Data

Specimen Type:	Resection:left buccal and neck dissection
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 5.0 cm Tumor thickness: 1.5 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.2 cm Margins: deep, inferior, superior, lateral
Pathologic Staging (pTNM):	pT3: Tumor of lip or oral cavity more than 4 cm in greatest dimension pN0: No regional lymph node metastasis for aerodigestive sites Number of regional lymph nodes examined: 42 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

verified by:

Electronically

[page 3 of 4]
Gross Description

1. The specimen is labeled with the patient's name and "left facial nodes". It consists of 4 pieces of fibroadipose tissue measuring 1 x 0.8 x 0.5 to 3.5 x 1 x 1cm. Multiple lymph nodes ranging from 0.4 x 0.3 x 0.3 to 2 x 1.3 x 0.6 cm are identified. Representative sections are submitted.

1A-1E one lymph node each

2. The specimen is labeled with the patient's name and "neck left level 2B". It consists of portion of fibroadipose tissue measuring 3 x 1.5 x 1.2cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 0.4 x 0.4 x 0.2 cm are identified. Representative sections are submitted.

2A multiple lymph nodes

3. The specimen is labeled with the patient's name and "neck left level 2". It consists of portion of fibroadipose tissue measuring 4 x 2.5 x 1.8 cm. Multiple lymph nodes ranging from 0.1 x 0.1 x 0.1 to 0.8 x 0.8 x 0.4 cm are identified. Representative sections are submitted.

3A-3B multiple lymph nodes each

3C one lymph node

4. The specimen is labeled with the patient's name and "neck left level 3". It consists of portion of fibroadipose tissue measuring 7 x 4 x 1.5 cm. Multiple lymph nodes ranging from 0.3 x 0.2 x 0.2 to 1.2 x 1 x 0.6 cm are identified. Representative sections are submitted.

4A multiple lymph nodes

4B-4C one lymph node each

5. The specimen is labeled with the patient's name and "neck left level 4". It consists of portion of fibroadipose tissue measuring 3 x 2 x 2 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.1 x 0.9 x 0.8 cm are identified. Representative sections are submitted.

5A multiple lymph nodes

5B two lymph nodes

6. The specimen is labeled with the patient's name and "neck left level 1". It consists of portion of fibroadipose tissue measuring 8 x 3 x 3 cm. A unremarkable submandibular gland measures 4 x 3 x 1.8 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 0.8 x 0.8 x 0.4 cm are identified. Representative sections are submitted.

6A submandibular gland

6B one lymph node

6C multiple lymph nodes

7. The specimen is labeled with the patient's name and "left buccal mass stitch anterior". It consists of an oriented portion of mucosa with a lateral triangle of skin on the lateral side of the specimen. The specimen measures 4.0 cm SI x 1.8 cm ML x 6.7 cm AP. The skin measures 3.3 SI x 0.3 ML cm and is grossly unremarkable. The resection margin is painted with silver nitrate. The tumor in the buccal mucosal is raised, ulcerated and measures 3.5 SI x 1.5 ML x 5.0 AP cm. The lesion is located at 0.2 cm from the inferior margin, 0.5 cm from the posterior margin, 0.4 cm from the anterior margin, 0.2 cm from the superior margin, 0.2 cm from the lateral margin, and 0.4cm from the skin.

7A inferior margin

7B posterior margin

7C anterior margin

7D superior margin

7E lateral margin

7F skin and tumor

7G-7J tumor

[page 4 of 4]
8. The specimen is labeled with the patient's name and as "Oral cavity posterior margin". It consists of a fragment of tissue measuring 1.1 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

8A frozen section

9. The specimen is labeled with the patient's name and as "superior margin". It consists of a fragment of tissue measuring 1 x 0.5 x 0.1 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

9A frozen section

10. The specimen is labeled with the patient's name and as "deep fat pad". It consists of a fragment of tissue measuring 1.2 x 1 x 0.5 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

10A frozen section

11. The specimen is labeled with the patient's name and as "anterior margin". It consists of a fragment of tissue measuring 1.1 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

11A frozen section

12. The specimen is labeled with the patient's name and as "inferior alveolar margin". It consists of 2 fragment of tissue measuring 0.6 x 0.1 x 0.1 and 0.7 x 0.3 x 0.1 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

12A frozen section

13. The specimen is labeled with the patient's name and as "deep margin". It consists of a fragment of tissue measuring 0.7 x 0.3 x 0.1 cm. The specimen is submitted in toto for frozen section. The specimen is kept frozen as per research protocol.

13A frozen section

Quick Section Diagnosis

8. Posterior margin – [REDACTED]
-Negative for malignancy. [REDACTED]
9. Superior margin – [REDACTED]
-Negative for malignancy. [REDACTED]
10. Deep fat pad – [REDACTED]
-Negative for malignancy. [REDACTED]
11. Anterior margin – [REDACTED]
-Negative for malignancy. [REDACTED]
12. Inferior alveolar margin – [REDACTED]
-Negative for malignancy. [REDACTED]
13. Deep anterior – [REDACTED]
-Negative for malignancy. [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 306e08c6-a5ac-430b-b523-e5ca600b8b76 (TCGA-CQ-6220.EDFFEF26-03F4-48BF-B619-B6A0669C84C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).